Surgical pathology report (de-identified scan), TCGA case TCGA-J8-A3O2, project TCGA-THCA (Thyroid Carcinoma), tissue source site Mayo Clinic, specimen TCGA-J8-A3O2-06A (Metastatic).

[page 1 of 5]
SurgPath Final
Temporary Copy

Page 1 of 1

FINAL DIAGNOSIS

- A) Left inferior parathyroid, biopsy: Benign adipose and atrophic thymic tissue.

COMMENT: CD3 and TdT stains are positive.

- B) Thyroid gland with central compartment nodes, excision: Well differentiated papillary adenocarcinoma (3.5 cm in diameter), left lobe of thyroid, focally extending to involved inked surgical margin and beyond the capsule of the thyroid into adjacent adipose tissue. Sections of the right thyroid gland show multiple foci of adenocarcinoma which measure up to 0.3 cm in maximum dimension. Thirteen of fourteen central compartment lymph nodes show metastatic tumor and measure up to 1.5 cm in greatest dimension.

- C) Tumor left Berry's ligament, biopsy: Metastatic well differentiated papillary adenocarcinoma.
- D) Right paratracheal lymph nodes, excision: Metastatic well differentiated papillary adenocarcinoma in three of three lymph nodes.
- E) Anterior mediastinal contents: Metastatic well differentiated adenocarcinoma involving one of one lymph node, measuring 1.5 cm in diameter. The rest of the specimen consists of fat replaced, atrophic thymus gland.
- F) Thymus, excision: Atrophic thymus.
- G) Right neck contents, anterior, excision: Metastatic well differentiated papillary adenocarcinoma in one of seven lymph nodes, measuring 2.0 cm in maximum dimension.
- H) Right posterior neck contents, excision: Metastatic well differentiated papillary adenocarcinoma in one of 48 lymph nodes, measuring up to 1.0 cm in diameter.
- I) Left anterior neck contents, excision: Metastatic well differentiated papillary adenocarcinoma in two of 25 lymph nodes, measuring up to 2.5 cm in greatest dimension.

1CD-0-3
Carcinoma, papillary, thyroid 8260/3
Met. Site: lymph nodes, neck 877.0
CQcF Site: Neck, NOS (carcinoma) 644.4

10/5/2012

[page 2 of 5]
SurgPath Final
Temporary Copy

Page 2 of 4

J) Left posterior neck contents, excision: Metastatic well differentiated papillary adenocarcinoma in two of 8 lymph nodes forming 4.0 and 3.5 cm in diameter masses.

B: Thyroid Gland
HISTOLOGIC TYPE:
Papillary carcinoma
Classical (usual)
TUMOR FOCALITY:
Multifocal (specify):

TUMOR SIZE:
Greatest Dimension: 3.5 cm
HISTOLOGIC GRADE:
G1: Well differentiated

PRIMARY TUMOR (pT):
pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)

REGIONAL LYMPH NODES (pN):
pN1b: Metastases to unilateral, bilateral or contralateral cervical (Levels I, II, III, IV, V) or retropharyngeal or superior mediastinal lymph nodes (Level VII).

NUMBER OF LYMPH NODE(S) INVOLVED: 23

NUMBER OF LYMPH NODE(S) EXAMINED: 106
LYMPH NODE, EXTRANODAL EXTENSION:

Present
EXTRATHYROIDAL EXTENSION:
Present
Minimal

~electronic signature~

SPECIMEN RECEIVED

[page 3 of 5]
- A) RULE OUT LEFT INFERIOR PARATHYROID, F/S
- B) THYROID GLAND WITH CENTRAL COMPARTMENT NODES, F/S
- C) TUMOR LEFT BERRY'S LIGAMENT
- D) RIGHT PARATRACHEAL LYMPH NODES
- E) ANTERIOR MEDIASTINUM CONTENTS
- F) THYMUS
- G) RIGHT ANTERIOR NECK CONTENTS
- H) RIGHT POSTERIOR NECK CONTENTS
- I) LEFT ANTERIOR NECK CONTENTS
- J) LEFT POSTERIOR NECK CONTENTS

FROZEN SECTION

- A) Rule out left inferior parathyroid, biopsy: Lymphoid tissue with squamous epithelial rest; atrophic thymus not excluded.
- B) Thyroid gland with central compartment lymph nodes, excision: Papillary thyroid adenocarcinoma (3.5 cm in diameter), with metastasis and replacement of multiple adjacent lymph nodes.

GROSS DESCRIPTION

A) Received fresh for frozen section labeled "rule out left inferior parathyroid" is an irregular portion of red/tan soft tissue weighing 30 mg and measuring 0.5 cm in greatest dimension. The specimen is entirely submitted for frozen section as A1.

B) Received fresh for frozen section labeled "thyroid gland with central compartment lymph nodes" is a thyroidectomy specimen with attached fatty soft tissue weighing 38.0 grams and measuring 10.0 x 9.0 x 2.0 cm overall. The specimen is inked with black ink. The thyroid is serially sectioned to reveal a 3.5 cm in greatest dimension white/tan tumor mass, which focally extends to the inked surgical margins. This mass is located within the left lobe of the thyroid. The remaining thyroid parenchyma is beefy red/tan. Multiple enlarged indurated lymph nodes are identified within the surrounding fatty soft tissue measuring up to 1.5 cm in greatest dimension. On transection, these lymph nodes appear grossly replaced by tumor. Touch preps are made of the lesion. A representative section of the largest lymph node is submitted for frozen section as B1. A representative section of the tumor mass within the left lobe of the thyroid is submitted for frozen section as B2, B3 through B6 additional sections of tumor mass within left lobe, B7 representative uninvolved left lobe, B8 and B9 representative sections right lobe, B10 bisected lymph node, B11 bisected lymph node, B12 bisected lymph node, B13 bisected lymph node, B14 bisected lymph node, B15 bisected lymph node, B16 bisected lymph node, B17 bisected lymph node, B18 additional lymph nodes, B19

[page 4 of 5]
portions of fatty soft tissue with possible smaller embedded lymph nodes.

C) Received in formalin labeled "tumor left Berry's ligament" is an ovoid portion of white/tan soft tissue measuring 0.6 cm in greatest dimension. The specimen is submitted in cassette C1.

D) Received in formalin labeled "right paratracheal lymph nodes" are three portions of yellow lobulated node-bearing adipose tissue measuring 2.0 x 1.0 x 0.6 cm. Dissection yields three indurated lymph nodes measuring up to 1.0 cm in greatest dimension. These are submitted in cassette D1.

E) Received in formalin labeled "anterior mediastinum contents" is an irregular portion of yellow lobulated soft tissue measuring 5.0 x 3.5 x 1.5 cm. Dissection yields a 1.5 cm in greatest dimension apparent lymph node, which has been grossly replaced by tumor. This lymph node is divided and submitted in cassette E1. Additional portions of the surrounding soft tissue are submitted in E2 and E3.

F) Received in formalin labeled "thymus" is an unoriented portion of yellow lobulated soft tissue measuring 3.5 x 2.5 x 0.5 cm. The specimen is divided and submitted in F1 to F3.

G) Received in formalin labeled "right neck contents anterior" is an irregular portion of yellow lobulated node-bearing adipose tissue measuring 7.0 x 6.5 x 3.0 cm. Dissection yields a 2.4 cm in greatest dimension nodule, which displays a white/tan to tan/brown cut surface. A 4.0 cm in greatest dimension portion of sternocleidomastoid muscle is attached to the specimen. Multiple additional smaller lymph nodes are identified. A portion of internal vein is identified and appears unremarkable. The remainder of the specimen displays yellow lobulated adipose tissue. Representative sections are submitted as follows: G1 sections of nodule, G2 sections of muscle and internal vein, G3 bisected lymph node, G4 additional lymph nodes, G5 to G8 additional sections of adipose tissue with possible smaller embedded lymph nodes.

H) Received in formalin labeled "right posterior neck contents" are three unoriented irregular portions of yellow lobulated node-bearing adipose tissue measuring 11.5 x 10.5 x 2.0 cm. Dissection yields multiple lymph nodes measuring up to 1.0 cm in greatest dimension. The largest lymph node is replaced by tumor. The remainder of the specimen displays a large amount of yellow lobulated adipose tissue. Representative sections are submitted as follows: H1 largest tumor replaced lymph node trisected, H2 trisected lymph node, H3 through H5 additional possible lymph nodes, H6 through H9 additional portions of adipose tissue with possible smaller

[page 5 of 5]
embedded lymph nodes.

I) Received in formalin labeled "left anterior neck contents" are two irregular portions of yellow lobulated node-bearing adipose tissue measuring 10.0 x 7.5 x 3.0 cm in aggregate. Dissection yields a 2.5 cm in greatest dimension tumor mass. Multiple additional possible lymph nodes are identified. The remainder displays a large amount of yellow lobulated adipose tissue. A portion of skeletal muscle is also received with the specimen. Representative sections are submitted as follows: I1 sections of largest tumor mass, K2 bisected lymph node, I3 bisected lymph node, I4 bisected lymph node, I5 pieces of skeletal muscle, I6 and I7 additional lymph nodes, I8 through I10 sections of adipose tissue with possible smaller embedded lymph nodes.

J) Received in formalin labeled "left posterior neck contents" are two irregular portions of yellow lobulated node-bearing adipose tissue measuring 10.0 x 10.0 x 4.0 cm. Dissection yields two large tumor masses measuring 4.0 and 3.5 cm in greatest dimension, respectively. Sectioning through the remainder of the specimen reveals multiple additional possible lymph nodes. A portion of beefy red/tan skeletal muscle is also received with the specimen. The remainder of the specimen displays a large amount of yellow lobulated adipose tissue. Representative sections are submitted as follows: J1 and J2 representative sections from largest tumor mass, J3 and J4 representative sections from second tumor mass, J5 bisected lymph node, J6 representative sections of skeletal muscle, J7 through J11 additional lymph nodes, J12 and J13 adipose tissue with possible smaller embedded lymph nodes.

CLINICAL INFORMATION

PAPILLARY CANCER THYROID AND NECK

IHPAA Discrepancy		

5/24/12

Source: NCI Genomic Data Commons file a0d33e5c-9698-4bd6-b586-d6269924d0be (TCGA-J8-A3O2.FCD2C9C3-B6BA-4D51-B6BC-B7773BE7CD39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).